Surgical pathology report (de-identified scan), TCGA case TCGA-18-3411, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Princess Margaret Hospital (Canada), specimen TCGA-18-3411-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. Pleura: PLEURAL DISEASE - APICAL SEGMENT RIGHT LOWER LOBE
2. Lymph node :Interlobar ST11
3. Lung :Both bronchial Margin Rt Upper Lobe. Single suture on tracheal margin, Double suture on Bronchial Margin
4. Lymph node : Rt low Paratracheal ST4R
Lymph node : Rt TB angle ST10R
5. Lymph node :Interlobar ST11
7. Lymph node : Subcarinal ST7

DIAGNOSIS

1. Apical segment right lower lobe wedge biopsy:
- Subpleural fibrosis and chronic inflammation, negative for malignancy.
2. Interlobar ST11:
- Negative for tumor, lymph node.
3. Right upper lobe lung lobectomy with sleeve resection:
- Poorly differentiated squamous cell carcinoma, central, 4.7 cm in greatest diameter. (pT2)
- Peri-tumoral chronic interstitial pneumonia and mucous plugging, consistent with obstructive pneumonitis.
- Tumor extensively infiltrates the peribronchial lymph nodes. (See comment)
- Bronchial resection margin negative for tumor.
- Tracheal resection margin negative for tumor.
- Remaining lung parenchyma shows moderate to marked centroacinar emphysematous changes.
4. Right low paratracheal ST4R:
- Positive for metastatic squamous cell carcinoma. (pN2)
5. Right TB angle ST10R:
- Positive for metastatic squamous cell carcinoma.

[page 2 of 4]
6. Interlobar ST11:

- Positive for metastatic squamous cell carcinoma in 1 of 3 lymph nodes.

7. Subcarinal ST7:

- Negative for tumor.

COMMENT

The peribronchial tissue circumference was painted with Indian ink, and the bronchus was serially cross-sectioned. One of the sections shows lymph node infiltrated by tumor, which also extends to the painted radial margin of this lymph node. The significance of this finding should be interpreted in the context of surgical procedure performed.

CLINICAL HISTORY
LUNG CANCER

GROSS DESCRIPTION

1. The specimen container labeled with the patient's name and as "apical segment right lower lobe", contains fragments of tan hemorrhagic tissue measuring 3.0 x 1.5 x 0.3 cm received fresh. This is examined at intraoperative consultation by frozen section performed on part of the specimen. On sectioning there is a white circular lesion in the center measuring 0.5 x 0.3 cm. The specimen is submitted in toto as follows:
1A - frozen section representative section resubmitted
1B-1C - remainder of the specimen submitted in toto.

2. The specimen container labeled with the patient's name and as "interlobar ST11", contains a piece of greyish-brown node measuring 0.6 x 0.4 x 0.4 cm received in 10% buffered formalin.
2A - specimen bisected and submitted in toto.

3. The specimen container labeled with the patient's name and as "both bronchial margin right upper lobe, single suture on tracheal margin, double suture on bronchial margin", contains a lobe of lung received

[page 3 of 4]
[REDACTED]

fresh. This is examined at intraoperative consultation by frozen section performed on part of the specimen. The lobe of lung measures 14.0 x 10.5 x 6.7 cm. On the hilar area there are two tubular cartilaginous tissue noted both marked with stitch, one double stitch marking as bronchial margin and one single stitch marking as the tracheal margin. The tracheal margin measures 1.5 cm in diameter while the bronchial margin measures 1.0 cm in diameter. Surrounding this bronchial and tracheal area is an area of soft tissue, which is firm and is grey-tan in color. The peripheries of these peri-bronchial and tracheal margins are painted with India ink. The pleural surface generally is smooth, shiny except for an area measuring 3.0 x 2.0 cm. This area has some fibrous adhesions to the pleura. On further sectioning underneath this puckered area is a well-defined tumor mass measuring 4.7 x 2.5 x 2.5 cm. The cut surface of the tumor mass is grey-tan to tan-white in color. On further sectioning about 1.8 cm to this tumor is an area of firmness, yellowish-brown to grey in color or areas of consolidation noted measuring about 2.0 x 2.0 cm. The tumor is partly solid and some necrotic areas. The remainder of the lung tissue appears to be grossly unremarkable with no other discrete lesion noted. Two pieces of tumor, one piece of bronchial mucosa and one piece of normal lung tissue were taken for snap freezing. Sections are submitted as follows:

- 3A - frozen section, bronchial margin resubmitted
- 3B - frozen section tracheal margin resubmitted
(Tracheal margin broke after resection from major specimen).
- 3C - frozen section tracheal margin representative deeper section from site of break resubmitted
- 3D-3M - bronchial area (bronchus, tracheal) serially sectioned circumferentially in relation to tumor
- 3N-3P - representative section of tumor in relation to the pleura with fibrous adhesion
- 3Q-3R - representative sections of the tumor in relation to normal tissue
- 3S -3V - representative sections of adjacent area of the tumor area of consolidation
- 3W -3X - representative sections of normal lung tissue away from the tumor

4. The specimen container labeled with the patient's name and as "right low paratracheal ST4LR", contains a piece of black-tan node measuring 1.0 x 0.6 x 0.3 cm received in 10% buffered formalin.
- 4A - submitted in toto.

[page 4 of 4]
[REDACTED]

5. The specimen container labeled with the patient' s name and as " right TB angle ST10R", contains a piece of grey-tan node measuring 1.4 x 0.8 x 0.6 cm received in 10% buffered formalin.
5A - specimen bisected and submitted in toto.

6. The specimen container labeled with the patient' s name and as "interlobar ST11", contains two pieces of greyish-tan nodes measuring 0.9 x 0.6 x 0.5 cm and 1.2 x 0.6 x 0.4 cm received in 10% buffered formalin.
6A - submitted in toto.

The specimen container labeled with the patient' s name and as "subcarinal ST7", contains a piece of greyish-brown soft tissue measuring 1.6 x 1.0 x 0.7 cm received in 10% buffered formalin.
7A - submitted in toto.

[REDACTED]

QUICK SECTION

1A "Inflammatory changes identified no malignancy."..
3A " Bronchial margin negative for malignancy"
3B,3C " Tracheal margin negative for malignancy".

[REDACTED]

Source: NCI Genomic Data Commons file f1468cce-9eb3-4e04-b171-5a45f8058bf6 (TCGA-18-3411.03EFA03C-F8F9-43C3-9244-265BC02CBB5C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).